Gene-level copy-number profile of tumor specimen HCM-SANG-1315-C18-06A-01D-A80T-32 from HCMI case HCM-SANG-1315-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1315-C18-06A-01D-A80T-32: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 690f2635-d582-492d-a517-bd7b8aaac615.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1315-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/3aa4963a-cfce-4f80-bef9-a6af7dc92ef4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 1,334; copy number 2: 30,209; copy number 3: 20,156; copy number 4: 4,569; copy number 5: 1,978; copy number 6: 120; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:17,601,882–17,643,228, 9 genes: AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–2): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–2): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–2): IGHV3-43.
- chr17:18,450,244–18,551,705, 9 genes (within-gene range 0–2): KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,941 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes, copy number 7: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr9:12,134–89,850, 7 genes, copy number 5: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr11:45,929,319–48,170,841, 73 genes, copy number 5 (broad region; genes not listed).
- chr12:12,310–27,325,959, 684 genes, copy number 5–6 (broad region; genes not listed).
- chr12:133,181,409–133,238,549, 5 genes, copy number 5 (within-gene range 4–5): ZNF268, AC226150.1, ANHX, RNU6-717P, Y_RNA.
- chr17:46,243,606–46,487,141, 7 genes, copy number 5: MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P, NSFP1.
- chr20:87,250–16,053,197, 288 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr20:15,892,355–22,685,344, 131 genes, copy number 5 (broad region; genes not listed).
- chr20:25,099,105–47,786,616, 529 genes, copy number 5 (broad region; genes not listed).
- chr20:48,921,711–60,653,784, 214 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,334. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
